Somatic mutation profile of tumor specimen TARGET-10-PARTLY-09A (aliquot TARGET-10-PARTLY-09A-01D) from TARGET case TARGET-10-PARTLY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.3 years (4,492 days).
Specimen TARGET-10-PARTLY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95f3b39e-0320-463a-bf9b-cad54c331760.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARTLY-10A (Blood Derived Normal), aliquot TARGET-10-PARTLY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d19e548-b8e7-4268-b8f3-45b8b477616e

The open-access MAF lists 30 somatic variants for this specimen: 23 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Nonsense Mutation 4, Silent 4, Intron 2, Frame Shift Ins 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK | c.16087G>A p.V5363M | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1408151343, COSV57216024; called by muse, mutect2, varscan2
- AKAP9 | c.7585G>T p.E2529* (on ENST00000359028; = p.E2505* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as COSV62348304; called by muse, mutect2, varscan2
- ARHGAP5 | c.352C>A p.R118S | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100565487; called by muse, mutect2
- CACNA1D | c.3995G>A p.R1332K (on ENST00000350061 / NM_001128840.3; = p.R1352K on NM_000720.4) | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.557); catalogued as rs148194645; called by muse, mutect2, varscan2
- DLG4 | c.2003A>G p.E668G (on ENST00000399506 / NM_001321075.3; = p.E711G on NM_001365.4) | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV57239159; called by muse, mutect2, varscan2
- EVC2 | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as rs530937415, COSV60394757; called by mutect2, varscan2
- GFI1 | c.1163G>T p.R388L | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV54042918, COSV99647424; called by muse, mutect2, varscan2
- HDAC7 | c.230_231insGGGCC p.S78Gfs*5 (on ENST00000427332; = p.S117Gfs*5 on NM_015401.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 10/59 reads (17%) | catalogued as COSV50367611; called by mutect2, pindel, varscan2
- MAP2 | c.2401G>T p.V801F | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52293729; called by muse, mutect2, varscan2
- MTBP | c.517T>G p.S173A | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV59963550; called by muse, mutect2, varscan2
- SMCHD1 | c.1900T>C p.Y634H | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs373093731; called by muse, mutect2, varscan2
- TRIM49B | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 98/234 reads (42%) | catalogued as rs755282956; called by muse, mutect2, varscan2
- ADGRL2 | c.593C>A p.T198K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by mutect2, varscan2
- C6orf201 | c.374C>A p.T125K | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.107); called by muse, mutect2
- CCNQ | c.293dup p.N98Kfs*5 | Frame Shift Ins (INS) | VAF 49/75 reads (65%) | called by mutect2, pindel, varscan2
- DNMT3A | c.820G>T p.A274S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GDPGP1 | c.595C>A p.P199T | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- PIEZO2 | c.4444G>T p.D1482Y | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by mutect2, varscan2
- PKHD1L1 | c.5321C>A p.T1774N | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- PTPRJ | c.3712C>A p.H1238N | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SYNC | c.1234G>T p.E412* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | called by muse, varscan2
- THRA | c.1035C>A p.Y345* | Nonsense Mutation (SNP) | VAF 4/43 reads (9%) | called by mutect2, varscan2
- WDR87 | c.1846G>T p.A616S | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ALS2 | c.1341A>G p.K447= | Silent (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- HPD | c.801C>T p.I267= | Silent (SNP) | VAF 40/102 reads (39%) | catalogued as rs759434513; called by muse, mutect2, varscan2
- PAK2 | c.717C>T p.I239= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as rs144419620; called by muse, mutect2, varscan2
- UIMC1 | c.1953G>T p.V651= | Silent (SNP) | VAF 4/19 reads (21%) | called by muse, varscan2
- DOCK8 | c.1797+84G>T | Intron (SNP) | VAF 60/127 reads (47%) | called by muse, mutect2, varscan2
- PSMC3IP | c.337+235G>T | Intron (SNP) | VAF 3/15 reads (20%) | called by mutect2, varscan2
- VAPB | c.*2324C>A | 3'UTR (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
